Gene-level copy-number profile of tumor specimen TCGA-22-4593-01A from TCGA case TCGA-22-4593, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.7 years (28,385 days).
Specimen TCGA-22-4593-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.e331adfe-f905-4862-a25a-fa7a60189ef0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-4593-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d9e1879b-c535-494a-82ec-049536302c53

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 1,685; copy number 2: 20,238; copy number 3: 24,131; copy number 4: 7,302; copy number 5: 2,879; copy number 6: 1,406; copy number 7: 1,033; copy number 8: 712; copy number 9: 81; copy number 10: 25; copy number 11: 30; copy number 12: 1; copy number 13: 16; copy number 15: 17; copy number 17: 5; copy number 18: 2; copy number 22: 33; copy number 23: 39; copy number 27: 101; copy number 30: 1; copy number 35: 48; copy number 36: 8; copy number 51: 12; copy number 58: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-4593-01A-21D-1816-01): tumor purity 0.77, ploidy 2.71, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,314,246–10,612,723, 1 gene (within-gene range 0–2): PTPRD.
- chr9:8,858,127–9,803,784, 5 genes: PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P, AL513422.1.
- chr14:46,651,010–46,651,781, 1 gene: RPL10L.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,168 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:84,958,989–89,048,434, 35 genes, copy number 9 (within-gene range 3–9): CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50.
- chr4:111,331,412–118,353,003, 91 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr4:122,815,771–122,922,968, 5 genes, copy number 10: AC021205.2, FGF2, AC021205.1, AC021205.3, NUDT6.
- chr4:131,112,748–133,575,208, 23 genes, copy number 8–17 (within-gene range 7–17): AC025554.1, RNU6-224P, LINC02377, AC105424.1, RN7SL205P, SNHG27, SNORA70, AC107393.1, RPL7AP28, AC096711.2, AC093916.1, AC096711.1, ELL2P2, AC114741.1, LINC01256, AARS1P1, AC115622.1, AC110751.1, AC105383.1, R3HDM2P1, PCDH10, AC108052.1, AC105252.1.
- chr5:58,198–45,895,970, 710 genes, copy number 8 (broad region; genes not listed).
- chr7:49,760,897–56,882,146, 140 genes, copy number 10–27 (broad region; genes not listed).
- chr11:68,707,440–70,436,584, 53 genes, copy number 15–23: TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,635,658, 3 genes, copy number 23: AP001271.1, AP001271.2, SHANK2-AS1.
- chr13:104,814,327–109,731,700, 49 genes, copy number 9–36 (within-gene range 6–36): RPL7P45, AL138954.1, DAOA-AS1, AL359751.2, AL359751.1, DAOA, AL359745.1, LINC00343, AL138701.1, AL138701.2, RNA5SP38, AL139379.1, LINC00460, RPL35P9, EFNB2, AL138689.2, AL138689.1, ARGLU1, LINC00551, LINC00443, ATP5MC1P5, AL163534.1, AL162574.2, PPIAP24, AL162574.1, AL162574.3, AL354741.1, FAM155A, SNORD31B, AL445649.1, MIR1267, FAM155A-IT1, AL359436.1, AL136964.1, LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, AL138694.1, HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1.
- chr13:113,122,799–113,364,148, 12 genes, copy number 51 (within-gene range 6–51): F10, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1.
- chr14:67,533,290–68,730,218, 32 genes, copy number 9 (within-gene range 2–9): PLEKHH1, PIGH, AL132640.1, AL132640.2, AL132640.3, Y_RNA, ARG2, AL049779.4, VTI1B, COX7A2P1, RNA5SP386, AL049779.1, RDH11, RDH12, RN7SL369P, RPL21P9, ZFYVE26, AL049779.3, RN7SL213P, AL049779.2, RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1.
- chr14:99,158,416–99,272,197, 3 genes, copy number 10: AL162151.1, BCL11B, AL109767.1.
- chr14:100,587,775–101,953,063, 142 genes, copy number 7 (broad region; genes not listed).
- chr14:101,969,364–101,969,601, 1 gene, copy number 7: AL118558.2.
- chr19:28,294,093–30,228,715, 48 genes, copy number 35: AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.
- chr19:56,567,468–56,626,481, 3 genes, copy number 58: ZNF470, SIGLEC31P, ZNF71.
- chr19:56,643,159–56,671,783, 2 genes, copy number 58: SMIM17, ZNF835.
- chr20:7,302,056–8,043,512, 9 genes, copy number 10: LINC01751, LINC01706, MIR8062, RN7SL547P, AL031679.1, AL021879.1, HAO1, TMX4, AL021396.1.
- chr20:8,097,824–8,256,918, 2 genes, copy number 10: PHKBP1, PLCB1-IT1.
- chr20:11,345,383–11,345,855, 1 gene, copy number 30: RPS11P1.
- chr20:13,368,291–13,996,443, 7 genes, copy number 7: AL121782.1, TASP1, GAPDHP2, ESF1, NDUFAF5, SEL1L2, RNU6-278P.
- chr20:14,003,508–14,758,056, 9 genes, copy number 7: RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2.
- chr20:17,187,510–17,484,578, 6 genes, copy number 9 (within-gene range 1–9): RNU6-27P, AL359511.1, RNU1-131P, AL359511.2, AL359511.3, PCSK2.
- chr20:33,912,323–64,313,132, 782 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 491. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
